Somatic mutation profile of tumor specimen HCM-CSHL-0384-D37-31B (aliquot HCM-CSHL-0384-D37-31B-01D-A79M-36) from HCMI case HCM-CSHL-0384-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 51.4 years (18,759 days).
Specimen HCM-CSHL-0384-D37-31B: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99f667bc-ca53-414f-a39a-ca0d0bc7bfe2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0384-D37-10A (Blood Derived Normal), aliquot HCM-CSHL-0384-D37-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7373f8cb-392a-48fb-8694-0513a621e0bf

The open-access MAF lists 120 somatic variants for this specimen: 90 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 26, Frame Shift Del 3, Nonsense Mutation 3, Frame Shift Ins 3, Intron 2, 3'UTR 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 56/318 reads (18%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KCTD7 | c.591C>T p.C197= (on ENST00000275532; = p.R211* on NM_153033.5) | Silent (SNP) | VAF 52/346 reads (15%) | catalogued as rs750811871; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 45/182 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMBN | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329082409; called by muse, mutect2
- APC | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 61/250 reads (24%) | catalogued as CM105842, COSV57327519; called by muse, mutect2, varscan2
- ARC | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs780927796; called by muse, mutect2, varscan2
- ARHGEF40 | c.4459dup p.H1487Pfs*28 | Frame Shift Ins (INS) | VAF 56/220 reads (25%) | catalogued as rs758492903; called by mutect2, varscan2
- ATP8A2 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs747985877, COSV54937479; called by muse, mutect2, varscan2
- CCDC172 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781038484, COSV60937835; called by muse, mutect2, varscan2
- CCDC175 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs199964220; called by muse, mutect2, varscan2
- CELSR3 | c.7336G>A p.V2446M | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759534857, COSV99375101; called by muse, mutect2, varscan2
- CHRNB2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1415028557; called by muse, mutect2, varscan2
- COL6A3 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs575412915, COSV55101444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.8765G>A p.R2922H | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148539877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK8 | c.4249G>A p.A1417T | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as rs1199786455; called by muse, mutect2, varscan2
- DSEL | c.968G>T p.W323L | Missense Mutation (SNP) | VAF 102/437 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100025713; called by muse, mutect2, varscan2
- EIF5B | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs751828370, COSV99177199; called by muse, mutect2, varscan2
- ERG | c.1121G>A p.R374H (on ENST00000398919 / NM_001243428.1; = p.R350H on NM_004449.4) | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55728243, COSV55731950; called by muse, mutect2, varscan2
- FERMT2 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 92/459 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58408179; called by muse, mutect2, varscan2
- GALNT12 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.75); catalogued as rs1256927785, COSV66662155; called by muse, mutect2, varscan2
- GHRHR | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754386566; called by muse, mutect2, varscan2
- GRAMD1B | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs780877280, COSV59205493; called by muse, mutect2, varscan2
- IGHM | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); catalogued as rs868946379; called by muse, mutect2
- IRX4 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770961282, COSV51474480, COSV51475669; called by muse, mutect2, varscan2
- KCNA1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66836546; called by muse, mutect2
- KCNA3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63901929; called by mutect2, varscan2
- KHDC3L | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as rs866082650, COSV64859035; called by muse, mutect2
- LAMB4 | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs747592570, COSV52730857; called by muse, mutect2, varscan2
- LIG4 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as rs187323251; called by muse, mutect2, varscan2
- MAN2A2 | c.24_25del p.C10Wfs*45 | Frame Shift Del (DEL) | VAF 32/178 reads (18%) | catalogued as rs768881302; called by mutect2, varscan2
- MMP15 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.068); catalogued as rs1037153021; called by muse, mutect2, varscan2
- MRC1 | c.2770C>T p.R924* | Nonsense Mutation (SNP) | VAF 92/338 reads (27%) | catalogued as rs782352494; called by mutect2, varscan2
- NLRP1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as rs200012608; called by muse, mutect2, varscan2
- NUP214 | c.3125A>G p.H1042R | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.086); catalogued as rs764771543; called by muse, mutect2, varscan2
- OR2T4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 104/478 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs756078095, COSV63544824; called by muse, mutect2, varscan2
- PCDH15 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1455035148, COSV57321053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA5 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs1554128615, COSV65350931; called by muse, mutect2, varscan2
- PDE10A | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 73/483 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866168774, COSV63092169; called by muse, mutect2
- PIK3CG | c.2657C>T p.T886M | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV63249761; called by muse, mutect2, varscan2
- PLEC | c.11833G>A p.G3945S (on ENST00000322810 / NM_201380.4; = p.G3835S on NM_000445.5) | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM151763; called by muse, mutect2, varscan2
- PLXNB3 | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs782757118; called by muse, mutect2, varscan2
- PSME4 | c.2918G>A p.R973H | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs763188055; called by muse, mutect2, varscan2
- PTCHD4 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs371181867; called by muse, mutect2, varscan2
- RAPSN | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs759579462; called by muse, mutect2, varscan2
- RSAD2 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 86/324 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201120739; called by muse, mutect2, varscan2
- SCN1A | c.1224C>A p.F408L | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57664475, COSV57679850; called by muse, mutect2
- SLC13A5 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs201674669, COSV53421201; called by mutect2, varscan2
- SLFN12 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 88/316 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as rs143225670; called by muse, mutect2, varscan2
- SOX11 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs750131174; called by muse, mutect2, varscan2
- STX10 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.307); catalogued as rs751947745, COSV52834013; called by muse, mutect2, varscan2
- TJP1 | c.3235C>T p.R1079* | Nonsense Mutation (SNP) | VAF 82/309 reads (27%) | catalogued as COSV62043997; called by muse, varscan2
- TOR4A | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs756370946; called by muse, mutect2, varscan2
- TRIM7 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs772954194; called by muse, mutect2, varscan2
- TTN | c.5774T>G p.V1925G (on ENST00000591111; = p.V1879G on NM_003319.4) | Missense Mutation (SNP) | VAF 97/397 reads (24%) | PolyPhen probably damaging (0.998); catalogued as COSV100593866; called by muse, mutect2, varscan2
- TULP4 | c.2920G>T p.A974S | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV65577334; called by muse, mutect2, varscan2
- ZC3H4 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756950439, COSV53410194; called by muse, mutect2, varscan2
- ALPP | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ARHGEF4 | c.1792C>A p.L598I | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by mutect2, varscan2
- BASP1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPSF6 | c.720_749del p.L241_P250del | In Frame Del (DEL) | VAF 60/284 reads (21%) | called by mutect2, varscan2
- CSMD3 | c.2229T>A p.N743K (on ENST00000297405 / NM_001363185.1; = p.N639K on NM_052900.3) | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAW1 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); called by muse, mutect2
- DYNC2H1 | c.2641G>T p.D881Y | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ETV4 | c.46T>C p.Y16H | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- FBXL4 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- GPR156 | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HELLS | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by mutect2, varscan2
- HMCN1 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 105/427 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INKA1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JMJD1C | c.1909A>C p.K637Q | Missense Mutation (SNP) | VAF 85/368 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- KCNH7 | c.2861A>G p.D954G | Missense Mutation (SNP) | VAF 102/340 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF17 | c.2531T>G p.L844W | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KRT72 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- NDNF | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 85/322 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NKAIN4 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OR6C65 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- PAPPA2 | c.3128_3135del p.P1043Lfs*49 | Frame Shift Del (DEL) | VAF 37/152 reads (24%) | called by mutect2, varscan2
- PKHD1 | c.8791C>A p.H2931N | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PKHD1 | c.4825G>T p.D1609Y | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PLXNA1 | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RETSAT | c.1828A>T p.N610Y | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- RFNG | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- RIF1 | c.5533G>A p.E1845K | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- RORB | c.828G>C p.Q276H (on ENST00000396204 / NM_001365023.1; = p.Q265H on NM_006914.4) | Missense Mutation (SNP) | VAF 71/292 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SETX | c.3494C>T p.S1165F | Missense Mutation (SNP) | VAF 35/472 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- TCF7L2 | c.979_983dup p.G329Mfs*24 (on ENST00000355995 / NM_001367943.1; = p.G306Mfs*24 on NM_030756.5) | Frame Shift Ins (INS) | VAF 33/216 reads (15%) | called by mutect2, varscan2
- TEX13C | c.2257C>G p.L753V | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- TMCO5A | c.506A>C p.K169T | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZBTB4 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZMYM4 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF598 | c.1957_1973del p.L653Vfs*62 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | called by mutect2, varscan2
- ADGRE2 | c.276C>T p.Y92= | Silent (SNP) | VAF 68/288 reads (24%) | catalogued as rs376023757; called by muse, mutect2, varscan2
- ASTN2 | c.2952A>T p.P984= (on ENST00000313400 / NM_001365069.1; = p.P933= on NM_014010.5) | Silent (SNP) | VAF 60/246 reads (24%) | called by muse, mutect2, varscan2
- BCAM | c.846C>T p.R282= | Silent (SNP) | VAF 43/190 reads (23%) | catalogued as rs771831123, COSV54302776; called by muse, mutect2, varscan2
- BMP7 | c.30G>A p.A10= | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, varscan2
- C2CD6 | c.150G>T p.S50= | Silent (SNP) | VAF 46/142 reads (32%) | called by muse, mutect2, varscan2
- CFAP54 | c.6606T>C p.F2202= | Silent (SNP) | VAF 120/428 reads (28%) | called by muse, mutect2, varscan2
- DGCR8 | c.2280C>T p.S760= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as rs374499450; called by muse, mutect2, varscan2
- DOK2 | c.207C>T p.A69= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as rs757512119; called by muse, mutect2, varscan2
- EVC | c.885C>G p.T295= | Silent (SNP) | VAF 87/298 reads (29%) | catalogued as COSV53836531; called by muse, mutect2, varscan2
- F2 | c.1830G>A p.K610= | Silent (SNP) | VAF 49/205 reads (24%) | called by muse, mutect2, varscan2
- FBXO40 | c.1338C>T p.D446= | Silent (SNP) | VAF 70/242 reads (29%) | catalogued as rs764170628; called by muse, mutect2, varscan2
- GATA3 | c.1257C>A p.P419= | Silent (SNP) | VAF 63/303 reads (21%) | catalogued as rs768238506; called by muse, mutect2, varscan2
- GPR180 | c.264T>G p.G88= | Silent (SNP) | VAF 81/345 reads (23%) | called by muse, mutect2, varscan2
- PCDHA6 | c.2049G>A p.S683= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs1305649998, COSV65346227; called by muse, mutect2, varscan2
- PCDHB2 | c.1986G>A p.V662= | Silent (SNP) | VAF 39/218 reads (18%) | called by muse, mutect2, varscan2
- PCDHB8 | c.567C>T p.G189= | Silent (SNP) | VAF 34/163 reads (21%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.1623C>T p.S541= | Silent (SNP) | VAF 57/175 reads (33%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.795C>T p.T265= | Silent (SNP) | VAF 51/228 reads (22%) | catalogued as COSV54046688; called by muse, mutect2, varscan2
- PCDHGA6 | c.1869G>A p.T623= | Silent (SNP) | VAF 43/187 reads (23%) | catalogued as rs1032808913; called by muse, mutect2, varscan2
- PRKCSH | c.1365C>T p.P455= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs368834600; called by muse, varscan2
- RNFT2 | c.186C>A p.G62= | Silent (SNP) | VAF 36/121 reads (30%) | called by mutect2, varscan2
- SETBP1 | c.996C>A p.G332= | Silent (SNP) | VAF 45/215 reads (21%) | called by muse, mutect2, varscan2
- SOX17 | c.567C>T p.P189= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs780594698; called by muse, mutect2
- TMEM175 | c.42G>A p.P14= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as rs747420455, COSV53279605; called by muse, mutect2, varscan2
- TRBV19 | c.144C>T p.H48= | Silent (SNP) | VAF 77/265 reads (29%) | catalogued as rs17263; called by muse, mutect2, varscan2
- DOCK8 | c.53+342G>A | Intron (SNP) | VAF 43/167 reads (26%) | catalogued as rs201097337, COSV101213736, COSV66688303; called by muse, mutect2, varscan2
- KCNK12 | c.*8500C>A | 3'UTR (SNP) | VAF 65/239 reads (27%) | catalogued as COSV100010031; called by muse, mutect2, varscan2
- NRG1 | chr8:31640044 C>T | 5'Flank (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- VIPR2 | c.152-7447A>T | Intron (SNP) | VAF 77/294 reads (26%) | called by muse, mutect2, varscan2
